Somatic mutation profile of tumor specimen TCGA-D8-A140-01A (aliquot TCGA-D8-A140-01A-11D-A10Y-09) from TCGA case TCGA-D8-A140, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.7 years (22,900 days).
Specimen TCGA-D8-A140-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94bc1e89-216a-4449-ad08-078648ed4ac4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A140-10A (Blood Derived Normal), aliquot TCGA-D8-A140-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fcc45ac-8d80-4efa-b91d-db1a694b24d5

The open-access MAF lists 112 somatic variants for this specimen: 84 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 26, Nonsense Mutation 8, Frame Shift Ins 6, Frame Shift Del 2, Splice Site 1, 5'UTR 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL10 | c.136dup p.I46Nfs*4 | Frame Shift Ins (INS) | VAF 36/118 reads (31%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- AAK1 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68646227; called by muse, mutect2, varscan2
- ADGRG6 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.743); catalogued as COSV51599496; called by muse, mutect2, varscan2
- ALKBH5 | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52763790; called by muse, mutect2, varscan2
- ANK3 | c.12682G>A p.D4228N (on ENST00000280772 / NM_001320874.2; = p.D852N on NM_001149.3) | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.829); catalogued as COSV55077166; called by muse, mutect2, varscan2
- ANP32E | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV58483192; called by muse, mutect2, varscan2
- ANPEP | c.2831C>T p.T944M | Missense Mutation (SNP) | VAF 87/319 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376373199; called by muse, mutect2, varscan2
- ARHGEF28 | c.2914A>G p.K972E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55266949; called by muse, mutect2, varscan2
- AZIN1 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.698); catalogued as COSV61481041; called by muse, mutect2, varscan2
- BIRC6 | c.11905C>T p.H3969Y | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101428025; called by muse, mutect2
- BLK | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs763474991, COSV52051612, COSV52055530; called by muse, mutect2, varscan2
- C9orf72 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV101186496; called by muse, mutect2
- CARD14 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100712516; called by muse, mutect2
- CCDC9B | c.1307_1308insT p.C437Vfs*21 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | catalogued as COSV101233495; called by mutect2, varscan2
- CD5L | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as rs773798853, COSV63821903, COSV63823426; called by muse, mutect2, varscan2
- COPS3 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 131/367 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52007001; called by muse, mutect2, varscan2
- CRB2 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV63505152; called by muse, mutect2, varscan2
- DAOA | c.385A>G p.M129V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV61603409; called by muse, mutect2, varscan2
- FAT4 | c.10171G>T p.V3391F | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100627833; called by muse, mutect2
- FCHO2 | c.830G>T p.S277I | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV55111076; called by muse, mutect2, varscan2
- FKBP15 | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374222379; called by muse, mutect2, varscan2
- FMO1 | c.1488C>G p.F496L | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1175843214, COSV100707718; called by muse, mutect2
- FNDC3A | c.971T>C p.V324A (on ENST00000492622 / NM_001079673.2; = p.V268A on NM_014923.5) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV101001209; called by muse, mutect2
- FRMD4B | c.1456A>C p.K486Q | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as COSV68332800; called by muse, mutect2, varscan2
- GATA3 | c.1003dup p.D335Gfs*17 | Frame Shift Ins (INS) | VAF 32/113 reads (28%) | catalogued as COSV60519609; called by mutect2, pindel, varscan2
- GPC2 | c.557dup p.D187* | Frame Shift Ins (INS) | VAF 17/60 reads (28%) | catalogued as rs757531975; called by mutect2, pindel, varscan2
- GPR162 | c.1405G>A p.E469K (on ENST00000311268 / NM_019858.2; = p.E185K on NM_014449.2) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); catalogued as COSV51835918; called by muse, mutect2, varscan2
- GRIN2A | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as CD138237, COSV58053138; called by muse, mutect2, varscan2
- GRM4 | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65218311; called by muse, mutect2, varscan2
- HELT | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58820429; called by muse, mutect2, varscan2
- HS2ST1 | c.74T>G p.L25R | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.293); catalogued as COSV59356851; called by muse, mutect2, varscan2
- IRS4 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV64532592; called by muse, mutect2, varscan2
- ITPR1 | c.1045G>T p.E349* (on ENST00000354582; = p.E334* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 43/140 reads (31%) | catalogued as COSV56999595; called by muse, mutect2, varscan2
- KCNK13 | c.370A>T p.K124* | Nonsense Mutation (SNP) | VAF 45/174 reads (26%) | catalogued as COSV56416678; called by muse, mutect2, varscan2
- KXD1 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99723633; called by muse, mutect2
- KYAT3 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.947); catalogued as rs1440582184, COSV99555872; called by muse, mutect2
- MAEL | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV63112622; called by muse, mutect2, varscan2
- MAGI2 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs760517354, COSV62654789; called by muse, mutect2, varscan2
- MAN2A1 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1196704660, COSV54857248; called by muse, mutect2, varscan2
- MFGE8 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776606175, COSV51557517; called by muse, mutect2, varscan2
- MLLT10 | c.2053C>T p.L685F (on ENST00000307729 / NM_001195626.3; = p.L701F on NM_004641.3) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV57002769, COSV57005162; called by muse, mutect2, varscan2
- NCOA3 | c.4010C>T p.S1337L (on ENST00000371998 / NM_181659.3; = p.S1333L on NM_006534.4) | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs148634537; called by muse, mutect2, varscan2
- NEXMIF | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV50081726; called by muse, mutect2, varscan2
- NPAS3 | c.2003C>T p.P668L (on ENST00000356141 / NM_001164749.2; = p.P636L on NM_022123.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1411310504, COSV100640477, COSV60856344; called by muse, mutect2, varscan2
- NUDT10 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1485048141, COSV62854257; called by muse, mutect2, varscan2
- NUP107 | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.086); catalogued as COSV57497464; called by muse, mutect2, varscan2
- OR10AG1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV56634520, COSV56635033; called by muse, mutect2
- OR7A5 | c.677A>T p.H226L | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV100457679; called by muse, mutect2
- PDE1B | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.825); catalogued as rs867519839, COSV54491410, COSV54495541; called by muse, mutect2, varscan2
- PEAK1 | c.80A>G p.H27R | Missense Mutation (SNP) | VAF 85/248 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56941775; called by muse, mutect2, varscan2
- PLEKHG3 | c.1964C>T p.T655I (on ENST00000394691; = p.T711I on NM_001308147.2) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1278892674, COSV55982992; called by muse, mutect2, varscan2
- PLPP4 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 154/395 reads (39%) | catalogued as COSV64829386; called by muse, mutect2, varscan2
- RAB30 | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 104/200 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52628110, COSV52628516; called by muse, mutect2, varscan2
- RADX | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV65319825; called by muse, mutect2, varscan2
- RAN | c.329del p.R110Qfs*22 | Frame Shift Del (DEL) | VAF 37/183 reads (20%) | catalogued as COSV54563471; called by mutect2, pindel, varscan2
- RC3H2 | c.2117A>G p.Y706C | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1437653350, COSV61802151; called by muse, mutect2, varscan2
- RP1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs1488188331, COSV55124548; called by muse, mutect2, varscan2
- RPL21 | c.278T>G p.I93S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV99699234; called by muse, mutect2
- SCN1A | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 109/544 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); catalogued as CD096202, COSV100319791; called by muse, mutect2, varscan2
- SEC13 | c.258G>A p.W86* (on ENST00000350697 / NM_183352.3; = p.W89* on NM_030673.4) | Nonsense Mutation (SNP) | VAF 44/158 reads (28%) | catalogued as rs746203143, COSV61601343, COSV61602328; called by muse, mutect2, varscan2
- SEC61A1 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV54578556; called by muse, mutect2, varscan2
- SIGLEC7 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58317516; called by muse, mutect2, varscan2
- SLC12A6 | c.2784C>G p.F928L (on ENST00000354181 / NM_001365088.1; = p.F877L on NM_005135.2) | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV51630522; called by mutect2, varscan2
- SLC20A1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 94/275 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.192); catalogued as COSV55612819; called by muse, mutect2, varscan2
- SLC22A25 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV60598497; called by muse, mutect2, varscan2
- SLC26A9 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs762926935, COSV61601137, COSV61604938; called by muse, mutect2, varscan2
- SLC35B2 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV51489073, COSV51491434; called by muse, mutect2, varscan2
- SLC66A1 | c.804+1G>A p.X268_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as rs758915063, COSV64320940; called by muse, mutect2, varscan2
- SRSF9 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs139360328; called by muse, mutect2, varscan2
- STAC2 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV61066480; called by muse, mutect2, varscan2
- SUCO | c.2648C>T p.T883I | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99742317; called by muse, mutect2
- TEX14 | c.1393A>T p.K465* (on ENST00000240361 / NM_001201457.2; = p.K459* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 41/329 reads (12%) | catalogued as rs1294690521, COSV53619798, COSV99541790, COSV99544006; called by muse, mutect2, varscan2
- TMTC4 | c.1508G>A p.R503K (on ENST00000376234 / NM_001350577.2; = p.R522K on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60893385; called by muse, mutect2, varscan2
- TSGA13 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV58406637; called by muse, mutect2, varscan2
- VPS26A | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1461148219, COSV54969213; called by muse, mutect2, varscan2
- ZFR2 | c.54C>T p.S18= | Splice Region (SNP) | VAF 13/22 reads (59%) | catalogued as rs772236830, COSV53602454; called by muse, mutect2, varscan2
- ZNF281 | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV54169312; called by muse, mutect2, varscan2
- ZNF347 | c.456C>A p.Y152* | Nonsense Mutation (SNP) | VAF 60/161 reads (37%) | catalogued as COSV61970529; called by muse, mutect2, varscan2
- ZNF492 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.713); catalogued as COSV101513966, COSV71761939; called by muse, mutect2
- ZNF75A | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV73039680; called by muse, mutect2, varscan2
- ZP4 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 44/208 reads (21%) | catalogued as COSV63913213; called by muse, mutect2, varscan2
- FAM166A | c.21dup p.D8Rfs*59 | Frame Shift Ins (INS) | VAF 60/242 reads (25%) | called by mutect2, pindel, varscan2
- MYCT1 | c.86del p.F29Sfs*28 | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | called by mutect2, pindel, varscan2
- OBSCN | c.18253dup p.Y6085Lfs*75 | Frame Shift Ins (INS) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- ADARB1 | c.417G>A p.L139= | Silent (SNP) | VAF 80/169 reads (47%) | catalogued as rs753361667, COSV62347371; called by muse, mutect2, varscan2
- AUTS2 | c.3489G>A p.E1163= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV61425239; called by muse, mutect2, varscan2
- GK2 | c.1410C>T p.S470= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as rs752527731, COSV62628107; called by muse, mutect2, varscan2
- GRIPAP1 | c.2412C>T p.T804= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs1557060043, COSV54415580; called by muse, mutect2, varscan2
- GRM6 | c.2322C>T p.G774= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs763674392, COSV51436365; called by muse, mutect2, varscan2
- KNDC1 | c.3687C>T p.S1229= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV58844564; called by muse, mutect2, varscan2
- KRT18 | c.546C>A p.I182= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV66316580; called by muse, mutect2, varscan2
- KRT76 | c.840C>T p.R280= | Silent (SNP) | VAF 42/129 reads (33%) | catalogued as rs1565672792, COSV60121656; called by muse, mutect2, varscan2
- MAU2 | c.601C>T p.L201= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV99448472; called by muse, mutect2
- MTMR11 | c.1128C>T p.R376= (on ENST00000439741 / NM_001145862.2; = p.R304= on NM_181873.3) | Silent (SNP) | VAF 28/246 reads (11%) | catalogued as rs782128829, COSV99641035; called by muse, mutect2, varscan2
- MUC16 | c.39366T>C p.S13122= | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as COSV101109725; called by muse, mutect2
- NACC1 | c.1176C>T p.G392= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV52835660; called by muse, mutect2, varscan2
- OR5AS1 | c.522C>T p.V174= | Silent (SNP) | VAF 81/313 reads (26%) | catalogued as rs1281125695, COSV57982948; called by muse, mutect2, varscan2
- OR8I2 | c.513C>T p.S171= | Silent (SNP) | VAF 31/230 reads (13%) | catalogued as COSV100135950; called by muse, mutect2, varscan2
- PFKFB1 | c.804C>T p.G268= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as rs1316131656, COSV66629177; called by muse, mutect2, varscan2
- PHKA1 | c.2836C>T p.L946= | Silent (SNP) | VAF 64/206 reads (31%) | catalogued as COSV100262671, COSV59810480; called by muse, mutect2, varscan2
- RNF123 | c.2965C>T p.L989= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100246504; called by muse, mutect2
- RYR1 | c.7908C>T p.F2636= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs1461283755, COSV62107909; called by muse, mutect2, varscan2
- SMARCA4 | c.1860C>T p.I620= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV60805978; called by muse, mutect2, varscan2
- TIAM2 | c.3225C>T p.G1075= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV51643945; called by muse, mutect2, varscan2
- TNC | c.2283G>A p.L761= | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as COSV100405315; called by muse, mutect2, varscan2
- TTC25 | c.340C>A p.R114= | Silent (SNP) | VAF 51/187 reads (27%) | catalogued as COSV66369041; called by muse, mutect2, varscan2
- ULK2 | c.2595G>A p.E865= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV64447868; called by muse, mutect2, varscan2
- USP39 | c.18G>A p.K6= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100083679; called by muse, mutect2
- YARS2 | c.624C>T p.L208= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV61402457; called by muse, mutect2, varscan2
- ZXDA | c.2382C>T p.G794= | Silent (SNP) | VAF 26/256 reads (10%) | catalogued as COSV100699386; called by muse, mutect2
- DLG3 | c.1820-1328C>A | Intron (SNP) | VAF 109/292 reads (37%) | catalogued as COSV52086230, COSV52088074; called by muse, mutect2, varscan2
- SCN1A | c.-2A>G | 5'UTR (SNP) | VAF 58/270 reads (21%) | catalogued as COSV100319792; called by muse, mutect2, varscan2
